Somatic mutation profile of tumor specimen TCGA-06-0169-01A (aliquot TCGA-06-0169-01A-01D-1490-08) from TCGA case TCGA-06-0169, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.8 years (25,127 days).
Specimen TCGA-06-0169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ecbb35e-c136-402f-a808-1e2b4386f66c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0169-10A (Blood Derived Normal), aliquot TCGA-06-0169-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/549673a1-ffd5-4018-8c3d-1da6cada340e

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, RNA 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2S3 | c.1394_1397del p.I465Sfs*4 | Frame Shift Del (DEL) | VAF 52/109 reads (48%) | catalogued as rs886040857; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADGRV1 | c.4985G>A p.R1662H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs193222107, COSV67993512; called by muse, mutect2, varscan2
- AMER3 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs548602521, COSV58465676; called by muse, mutect2, varscan2
- C9orf131 | c.2830A>G p.K944E | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.412); catalogued as rs1563969873, COSV56610080; called by muse, mutect2, varscan2
- CATSPERD | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.619); catalogued as rs757541319, COSV58464623; called by muse, mutect2, varscan2
- CCK | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.257); catalogued as COSV58183548; called by muse, mutect2, varscan2
- CLCN7 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51969394; called by muse, mutect2, varscan2
- DKK2 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.071); catalogued as rs374083904; called by muse, mutect2, varscan2
- DNAH11 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs752311298, COSV60975718; called by muse, mutect2, varscan2
- DSCAML1 | c.4931G>A p.G1644D (on ENST00000321322; = p.G1584D on NM_020693.4) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58382097; called by muse, mutect2, varscan2
- DYSF | c.4454T>C p.I1485T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs559940171, COSV50279555; called by muse, mutect2, varscan2
- FAM71B | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs376135369; called by muse, mutect2, varscan2
- FAT2 | c.6805C>A p.P2269T | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV55815572; called by muse, mutect2, varscan2
- GBP1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs140785577; called by muse, mutect2, varscan2
- GRB10 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV60008436; called by muse, mutect2, varscan2
- HDLBP | c.3233T>C p.I1078T | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60493072; called by muse, mutect2, varscan2
- HLA-B | c.1044G>A p.A348= | Splice Region (SNP) | VAF 25/128 reads (20%) | catalogued as rs750871285, COSV69522754; called by muse, mutect2, varscan2
- IL7 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs751462790, COSV55673477; called by muse, mutect2, varscan2
- KDELR1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58102789; called by muse, mutect2, varscan2
- KRT13 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs781291691, COSV55838986; called by muse, mutect2, varscan2
- KRT14 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs772876124, COSV51422838; called by muse, mutect2, varscan2
- MANF | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56544804; called by muse, mutect2, varscan2
- MRGPRX1 | c.478T>G p.L160V | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57109276; called by muse, varscan2
- NXPH1 | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs145299363, COSV68316902, COSV68319022; called by muse, mutect2
- OR2T6 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV63215930, COSV63216958; called by muse, mutect2, varscan2
- PCDHB9 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV53382763; called by muse, mutect2, varscan2
- PCLO | c.3073A>G p.K1025E | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as COSV61650265, COSV61659724; called by muse, mutect2, varscan2
- ROBO4 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60622293; called by muse, mutect2, varscan2
- SCN9A | c.4100G>A p.R1367H (on ENST00000303354; = p.R1356H on NM_002977.3) | Missense Mutation (SNP) | VAF 97/470 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs200566017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGIP1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs556202457, COSV52764694; called by muse, mutect2, varscan2
- TAS2R39 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.591); catalogued as rs890745343, COSV71470989; called by muse, mutect2, varscan2
- TENM3 | c.5702C>T p.T1901I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV69298839, COSV69316744; called by muse, mutect2, varscan2
- TEX15 | c.7151C>T p.T2384M (on ENST00000256246; = p.T2767M on NM_001350162.2) | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs759813914, COSV56342929; called by muse, mutect2, varscan2
- TMPRSS2 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755712060, COSV59821897; called by muse, mutect2
- ZC3H13 | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as COSV54449784; called by muse, mutect2, varscan2
- ZSWIM1 | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845859; called by muse, mutect2, varscan2
- MUC16 | c.19658del p.T6553Kfs*40 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- OR5D14 | c.432_441delinsT p.L145_V147del | In Frame Del (DEL) | VAF 56/229 reads (24%) | called by pindel, varscan2*
- TRPM4 | c.3131+2dup p.X1044_splice | Splice Site (INS) | VAF 46/205 reads (22%) | called by mutect2, pindel, varscan2
- ACP7 | c.879C>T p.N293= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs756183542, COSV58698542; called by muse, mutect2, varscan2
- BCAN | c.663A>G p.R221= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as COSV61259070; called by muse, mutect2, varscan2
- COL15A1 | c.2115G>A p.P705= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as rs778442724, COSV66642291; called by muse, mutect2, varscan2
- COL20A1 | c.543C>G p.V181= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV58925534; called by muse, mutect2, varscan2
- GPR139 | c.765G>A p.A255= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs1303527167, COSV58502068; called by muse, mutect2, varscan2
- GPR20 | c.1029C>T p.A343= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs778872590, COSV66684064; called by muse, mutect2, varscan2
- OR51L1 | c.186T>C p.Y62= | Silent (SNP) | VAF 34/335 reads (10%) | catalogued as COSV58625518; called by muse, mutect2, varscan2
- PKD1 | c.10308G>A p.Q3436= (on ENST00000262304 / NM_001009944.3; = p.Q3435= on NM_000296.4) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV51912712; called by muse, mutect2, varscan2
- PYHIN1 | c.1245C>A p.P415= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV63721787; called by muse, mutect2, varscan2
- RELN | c.2634G>A p.E878= | Silent (SNP) | VAF 38/260 reads (15%) | catalogued as COSV59028735; called by muse, mutect2, varscan2
- DCHS2 | n.209C>T | RNA (SNP) | VAF 25/90 reads (28%) | catalogued as rs370268335; called by muse, mutect2, varscan2
- TCP10L3 | n.1954C>T | RNA (SNP) | VAF 49/162 reads (30%) | catalogued as rs1396433188, COSV64750059; called by muse, mutect2, varscan2
- VPS11 | c.-1050C>T | 5'UTR (SNP) | VAF 9/37 reads (24%) | catalogued as rs1219631965, COSV56186735; called by muse, mutect2, varscan2
